TCGA case TCGA-DX-A6BF — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Lipomatous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f693eec9-cd6e-4696-882f-a6dffe481df9

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 82 years; Vital status: Alive.

Diagnoses (2)
1. Dedifferentiated liposarcoma (the primary disease): ICD-O-3 morphology code: 8858/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 82.3 years (30,071 days); Year of diagnosis: 2012; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Tumor focality: Multifocal.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis percent: 25; Necrosis present: Yes; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 3.1; Tumor length measurement: 8.5; Tumor width measurement: 6.4.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 19; Tumor length measurement: 38.3; Tumor width measurement: 26.2.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 1.4; Tumor length measurement: 4.5; Tumor width measurement: 3.5.
   Pathology details: Measurement type: Pathologic; Tumor burden: 51.3.
2. Recurrence of diagnosis 1 (Dedifferentiated liposarcoma). Age at diagnosis: 84.9 years (31,018 days); Days to diagnosis: 947 days (2.6 years); Prior treatment: Yes.

Follow-up (6 entries)
- Day 0 (initial diagnosis): Discontiguous lesion count: 3.
- Days to follow up: 63 days; Disease response: Tumor Free.
- Days to follow up: 186 days; Disease response: Tumor Free.
- Days to follow up: 277 days; Disease response: Tumor Free.
- Day 947 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 947 days (2.6 years).
- Days to follow up: 972 days (2.7 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-A6BF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 1,200 mg.
  Slide TCGA-DX-A6BF-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-A6BF-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-A6BF-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Retroperitoneum.
- Primary pathology: Margin status: Positive; Tumor total necrosis: Moderate Necrosis (>=10, <50%); Disease multifocal indicator: Yes; Discontinuous lesions count: 3; Locoregional recurrence indicator: No; Metastatic disease confirmed: No; Well diff liposarc prior diagnosis indicator: No.
- Primary pathology, Tumor sizes, Tumor size 1: Lesion pathologic depth: 19.0.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response.
- Follow-up form 3: Lost to follow-up: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 972 days; disease-specific survival: no event (censored), 972 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 947 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-A6BF-01A-11D-A306-01): tumor purity 0.59, ploidy 3.72, whole-genome doublings 1.
